CCDI case PBCHFE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and unspecified parts of mouth.
https://portal.gdc.cancer.gov/cases/d9d7bb0e-7b43-45be-ae88-47777917ae78

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Mandible; Age at diagnosis: 7.1 years (2,599 days).

Biospecimens (3 samples)
- Samples 0DRXE7, 0DRXEE (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRXEU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
